Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4870, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4870-01A (Primary Tumor).

Pathology Report

DIAGNOSIS

(A) LEFT RADICAL NEPHRECTOMY:

RENAL CELL CARCINOMA (11.5 CM MAXIMUM DIMENSION), CONVENTIONAL TYPE
(100% CLEAR CELLS),

FUHRMAN NUCLEAR GRADE 2, FOCALLY INVASIVE INTO PERINEPHRIC ADIPOSE
TISSUE AND

RENAL PELVICALYCEAL SYSTEM. (SEE COMMENT)

Margins of resection free of tumor.

Adrenal gland, no tumor present.

COMMENT

The renal cell carcinoma in the left kidney shows focal invasion into the perinephric adipose tissue. The tumor also invades into the renal pelvicalyceal system. The renal sinus adipose tissue and the renal vein are free of tumor. Multiple additional deeper sections were examined.

GROSS DESCRIPTION

(A) LEFT RADICAL NEPHRECTOMY - A left radical nephrectomy specimen (23.0 x 13.0 x 7.0 cm) including kidney (18.0 x 6.0 x 6.0 cm), adrenal gland (4.5 x 0.7 x 0.4 cm) and perinephric adipose tissue (ranging in thickness from 0.7 cm to 4.5 cm) present around the kidney.

A tumor (11.5 x 10.5 x 7.0 cm) is present, involving the lower pole of the kidney. It is well circumscribed, bright-yellow with central area of hyalinized, white-gray, gelatinous scarring measuring 5.0 cm in diameter. Focal areas of hemorrhage are noted within the tumor. The tumor is separated from the perinephric fat by capsule and does not grossly infiltrate it. The tumor pushes against the renal sinus, but does not appear to grossly invade the renal sinus adipose tissue. The renal vein is free of tumor.

The adjacent kidney is congested, but otherwise unremarkable. The adrenal consists of bright-yellow cortex and unremarkable medulla, devoid of any nodules.

Representative material is submitted for possible electron microscopy, and for the vaccine protocol.

INK CODE: Black- Gerota's fascia closest to the tumor.

SECTION CODE: A1, vascular and ureteral resection margin; A2-A13, tumor, including sections with perinephric fat; A14-A17, tumor with renal pelvis and renal sinus; A18, A19, unremarkable kidney; A20, adrenal gland, representative section.

CLINICAL HISTORY

None given.

SNOMED CODES

T-71000, M-83123

"Some tests reported here may have been developed and performance

Source: NCI Genomic Data Commons file f45be72e-93d4-436e-b324-06a034edb586 (TCGA-CJ-4870.B8521B74-EA3F-4EDE-81B6-697E1DD1BDFF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).